Surgical pathology report (de-identified scan), TCGA case TCGA-BR-8484, project TCGA-STAD (Stomach Adenocarcinoma), tissue source site Asterand, specimen TCGA-BR-8484-01A (Primary Tumor).

[page 1 of 3]
[Redacted]

[Redacted] Case ID	Gross Description	Microscopic Description	Diagnosis Details
[Redacted]			

[page 2 of 3]
Comments	Formatted Path Report
	STOMACH TISSUE CHECKLIST Specimen type: Gastrectomy Tumor site: Fundus Tumor size: 8 x 8 x 8 cm Tumor features: None specified Histologic type: Adenocarcinoma Histologic grade: Moderately differentiated Tumor extent: Serosa (visceral peritoneum) Lymph nodes: 2/7 positive for metastasis (Regional 2/7) Lymphatic invasion: Not specified Venous invasion: Not specified Perineural invasion: Not specified Margins: Not specified Evidence of neo-adjuvant treatment: Not specified Additional pathologic findings: Not specified Comments: None

	ID

[page 3 of 3]
Excision date	Laterality

Source: NCI Genomic Data Commons file 2eea5696-8e48-4ce0-b31e-477eec0cf87b (TCGA-BR-8484.EDB6A731-07DF-403A-BD4B-4844AA1B1138.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).